Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A28A, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A28A-01A (Primary Tumor).

ath (First Tumor)

Tumor Site:	Cecum Proximal
Date of Cancer Sample Procurement:	
Histology:	Adenocarcinoma
Description of other histology:	
Grade:	Moderately Differentiated
Mucinous:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No ☐ Yes ☐ Unknown
Host Response:	Lymphoid Aggregates
Crohn's like reaction	☐ None ☒ Yes ☐ Unknown
Plasma cell rich stroma	☐ No ☐ Yes ☐ Unknown
Growth Pattern:	☐ Expansile ☒ Invasive ☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No ☐ Yes ☐ Unknown
Angiolymphatic Invasion:	☒ No ☐ Yes ☐ Unknown
Mutator Phenotype:	☒ No ☐ Yes ☐ Unknown
Number of Slides	1
Garland Necrosis present:	☐ No ☒ Yes ☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	1
Pathologist Comment:	

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: Cecum C18.0 /w 5/3/11

Primary / Tumor Site Discrepancy		☒

Source: NCI Genomic Data Commons file c2ee198f-a751-43c0-a422-ae41c02504f6 (TCGA-DM-A28A.66BF2525-B76A-4BE5-8FDF-EAE8334F384E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).